Somatic mutation profile of tumor specimen ALCH-B505-TTP1-A (aliquot ALCH-B505-TTP1-A-1-0-D-A83F-36) from ALCHEMIST case ALCH-B505, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 56.0 years (20,446 days).
Specimen ALCH-B505-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 06c2fce0-b7bb-4dc3-b019-ed7b968467e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B505-NB1-A (Blood Derived Normal), aliquot ALCH-B505-NB1-A-1-0-D-A83F-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d83261e-9b1a-4bf1-9796-20d339a12f06

The open-access MAF lists 46 somatic variants for this specimen: 28 protein-altering or splice-affecting, 9 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 9, Intron 3, 5'Flank 3, 5'UTR 1, Nonsense Mutation 1, RNA 1, In Frame Del 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2236_2250del p.E746_A750del | In Frame Del (DEL) | VAF 78/672 reads (12%) | hotspot (GDC flag); catalogued as rs727504233, COSV51765066, COSV51849442; ClinVar: drug response; called by mutect2, pindel
- ATP1A3 | c.854C>T p.T285M (on ENST00000545399 / NM_001256214.2; = p.T272M on NM_152296.5) | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57484731; called by muse, mutect2, varscan2
- IGSF10 | c.7604C>T p.P2535L | Missense Mutation (SNP) | VAF 35/367 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99192376; called by muse, mutect2
- MLLT6 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 15/238 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1275796358; called by muse, mutect2
- MUC5AC | c.16094C>T p.P5365L | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.034); catalogued as rs964271175, COSV100611470; called by muse, mutect2
- MYH11 | c.301G>A p.V101M | Missense Mutation (SNP) | VAF 13/319 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375159635; ClinVar: uncertain significance; called by muse, mutect2
- MYO15A | c.6314G>A p.R2105Q | Missense Mutation (SNP) | VAF 30/288 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376459871, COSV99234224; called by muse, mutect2, varscan2
- NACA2 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 63/603 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs765470743, COSV71713090; called by muse, mutect2, varscan2
- OR56A1 | c.82C>A p.H28N | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.142); catalogued as COSV57362892; called by muse, varscan2
- PPARG | c.97G>A p.D33N (on ENST00000287820 / NM_015869.5; = p.D3N on NM_005037.7) | Missense Mutation (SNP) | VAF 34/322 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1215582219; called by muse, mutect2, varscan2
- RNF123 | c.3743C>T p.T1248I | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as rs764087552; called by muse, mutect2, varscan2
- ROR2 | c.1888A>C p.K630Q | Missense Mutation (SNP) | VAF 92/1040 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as rs1052671644; called by muse, mutect2
- ABCC3 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 24/460 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2
- AGO4 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 19/307 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); called by muse, mutect2
- BTBD3 | c.980T>G p.L327R | Missense Mutation (SNP) | VAF 12/302 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- FASTKD5 | c.938T>C p.I313T | Missense Mutation (SNP) | VAF 11/181 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.036); called by muse, mutect2
- FLNB | c.6448A>T p.K2150* | Nonsense Mutation (SNP) | VAF 28/414 reads (7%) | called by muse, mutect2
- KLHL38 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 22/348 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2
- MAST3 | c.3882G>C p.E1294D | Missense Mutation (SNP) | VAF 19/507 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); called by muse, mutect2
- MYLK3 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 15/216 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.283); called by muse, mutect2
- MYLK3 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 26/344 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.434); called by muse, mutect2
- PSEN2 | c.868C>G p.P290A | Missense Mutation (SNP) | VAF 60/661 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RAB40C | c.220_226del p.G74Sfs*75 | Frame Shift Del (DEL) | VAF 18/160 reads (11%) | called by mutect2, pindel, varscan2
- RNF14 | c.1315A>G p.R439G | Missense Mutation (SNP) | VAF 13/404 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.037); called by muse, mutect2
- TRMT61B | c.541A>C p.N181H | Missense Mutation (SNP) | VAF 35/348 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.154); called by muse, mutect2
- USP44 | c.1592A>T p.E531V | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); called by muse, mutect2
- ZBTB4 | c.2107G>C p.E703Q | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.075); called by muse, mutect2
- ZNF317 | c.234G>C p.Q78H | Missense Mutation (SNP) | VAF 18/306 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- DLGAP2 | c.1137C>T p.A379= | Silent (SNP) | VAF 10/270 reads (4%) | called by muse, mutect2
- MAGIX | c.801C>T p.G267= | Silent (SNP) | VAF 14/354 reads (4%) | catalogued as rs782318088; called by muse, mutect2
- MARCHF1 | c.87T>A p.A29= | Silent (SNP) | VAF 20/361 reads (6%) | called by muse, mutect2
- NDUFA9 | c.609G>A p.P203= | Silent (SNP) | VAF 26/337 reads (8%) | catalogued as rs751916214; called by muse, mutect2
- SOX7 | c.126G>A p.E42= | Silent (SNP) | VAF 9/169 reads (5%) | catalogued as COSV58730655; called by muse, mutect2
- SPIRE1 | c.822A>G p.V274= | Silent (SNP) | VAF 7/190 reads (4%) | called by muse, mutect2
- THAP3 | c.504A>G p.R168= (on ENST00000054650 / NM_001195753.1; = p.R167= on NM_001195752.1) | Silent (SNP) | VAF 72/458 reads (16%) | catalogued as rs749975066; called by muse, mutect2, varscan2
- TMEM8B | c.259C>T p.L87= | Silent (SNP) | VAF 9/116 reads (8%) | catalogued as rs201144289; called by muse, mutect2
- TNN | c.1866C>T p.S622= | Silent (SNP) | VAF 88/402 reads (22%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499114 A>C | 5'Flank (SNP) | VAF 16/236 reads (7%) | catalogued as rs766966793; called by muse, mutect2
- LINC00618 | chr14:96931352 G>A | 5'Flank (SNP) | VAF 49/441 reads (11%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85569G>C | Intron (SNP) | VAF 10/294 reads (3%) | catalogued as COSV72283319; called by muse, mutect2
- MIR548A1 | n.93G>T | RNA (SNP) | VAF 50/614 reads (8%) | called by muse, mutect2
- PLEKHA7 | chr11:16782817 G>A | 3'Flank (SNP) | VAF 18/370 reads (5%) | catalogued as rs1330824958; called by muse, mutect2
- PPARG | c.-14T>A | 5'UTR (SNP) | VAF 20/424 reads (5%) | called by muse, mutect2
- RUFY2 | c.1310+859C>T | Intron (SNP) | VAF 13/195 reads (7%) | catalogued as rs1369605441; called by muse, mutect2
- TMC1 | c.362+26A>T | Intron (SNP) | VAF 13/296 reads (4%) | called by muse, mutect2
- TVP23C | chr17:15565948 C>T | 5'Flank (SNP) | VAF 22/380 reads (6%) | catalogued as rs778663862; called by muse, mutect2
